Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A8O8, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A8O8-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: In bladder, it is invasive and protruded masse, ill - margins with 3.5x2.5x1cm in size, soft and gray surface.

Microscopic Description: Tumor is density. Tumor cells are hyperplastic to form papillary or trabeculae. Tumor cells have moderate and eosinophilic or clear cytoplasm. Nuclei are enlarged and varriability in shape and size, irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are present. Tumor invades in muscularis propria

Diagnosis Details: Infiltrating urothelial carcinoma, high-grade, infiltrating muscularis propria

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 3.5 x 2.5 x 1 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Poorly differentiated

Tumor extent: Muscularis propria

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: No

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
Carcinoma, urothelial NOS
8120/3
path
Carcinoma, transitional cell NOS
8120/3
Site: Bladder NOS
C67.9
JW 11/26/13

Source: NCI Genomic Data Commons file 1564ebb8-7b9a-411a-84e5-206cd882d365 (TCGA-E7-A8O8.F6B4EF0F-8E4C-4B07-B946-3D55CB975799.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).